FM case AD10355 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/b4a69d19-a5e3-437b-904e-acb4690e53f1

Female, 62.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
